Gene-level copy-number profile of tumor specimen TCGA-AN-A0FV-01A from TCGA case TCGA-AN-A0FV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.8 years (21,479 days).
Specimen TCGA-AN-A0FV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1df1f52c-ac80-480a-af35-772bd79ad3d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64a21b3e-6b86-44b9-81a9-1d5dd2de7a92

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,751; copy number 2: 24,730; copy number 3: 23,499; copy number 4: 9,199; copy number 5: 254; copy number 6: 26; copy number 8: 17; copy number 9: 9; copy number 11: 35; copy number 12: 17; copy number 13: 1; copy number 14: 97; copy number 15: 15; copy number 16: 2; copy number 18: 21; copy number 20: 1; copy number 21: 4; copy number 25: 29; copy number 26: 33; copy number 27: 7; copy number 28: 16; copy number 29: 5; copy number 32: 2; copy number 41: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FV-01A-11D-A011-01): tumor purity 0.55, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 355 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:31,687,215–31,708,455, 1 gene, copy number 16: PPP1R17.
- chr7:31,941,261–31,941,583, 1 gene, copy number 16: SNX2P2.
- chr7:43,866,558–44,849,568, 44 genes, copy number 14 (within-gene range 3–14): URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952.
- chr11:76,860,867–78,582,156, 47 genes, copy number 14–29: ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:83,455,012–85,627,922, 8 genes, copy number 13–27 (within-gene range 1–27): DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.3.
- chr11:85,452,282–87,025,777, 39 genes, copy number 14: AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8.
- chr11:87,094,734–87,096,585, 1 gene, copy number 14: XIAPP2.
- chr17:27,082,690–27,626,438, 15 genes, copy number 15 (within-gene range 2–15): TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1.
- chr17:29,197,071–29,254,494, 3 genes, copy number 12: AC005412.1, TWF1P1, CRYBA1.
- chr17:32,423,971–32,491,253, 6 genes, copy number 8: AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,495,536–32,686,484, 8 genes, copy number 8–9 (within-gene range 2–9): AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1.
- chr17:38,730,341–40,357,643, 79 genes, copy number 11–41 (within-gene range 2–41) (broad region; genes not listed).
- chr17:55,751,051–55,872,939, 2 genes, copy number 32 (within-gene range 3–32): PCTP, AC090618.1.
- chr17:57,744,495–57,834,749, 3 genes, copy number 9 (within-gene range 3–9): CCDC182, AC015845.2, RN7SKP94.
- chr17:58,050,789–58,417,595, 21 genes, copy number 18 (within-gene range 3–36): AC015813.8, AC015813.3, DYNLL2, AC015813.6, OR4D1, MSX2P1, OR4D2, EPX, AC005962.1, MKS1, LPO, AC005962.2, AC004687.3, MPO, TSPOAP1, TSPOAP1-AS1, AC004687.1, MIR142, MIR4736, SUPT4H1, AC004687.2.
- chr20:56,468,585–58,818,313, 61 genes, copy number 8–26 (broad region; genes not listed).
- chr20:63,981,132–64,313,132, 16 genes, copy number 28 (within-gene range 4–28): PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 1,751. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
